Surgical pathology report (de-identified scan), TCGA case TCGA-KP-A3W3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site British Columbia Cancer Agency, specimen TCGA-KP-A3W3-01A (Primary Tumor).

Anatomical Pathology

Case:

MRN:

PHN:

Ordering Physician:

- A. Uterus (with cervix), tubes and ovaries:
1. Endometrial high-grade serous carcinoma.
2. Tumour invades into the outer half of the myometrium.
3. Lymphovascular invasion identified.
4. Cervix, tubes and ovaries negative for tumour except for microscopic focus of serous intraepithelial carcinoma in the right tube.
5. Ovarian stromal hyperplasia.
- B. Peritoneal washings: Positive for malignant cells, consistent with serous carcinoma.

Clinical History as Provided by Submitting Physician:

Current cytology
Normal CA-125 Pap serous endo

ICD-O-3

carcinoma, serous, NOS
844113

Site: endometrium
C54.1

4-25-12
RO

Gross Description:

Received is a single container labelled with the patient's name, , demographics and UTERUS CERVIX OVARIES AND TUBES. It consists of the same weighing 184 gm. The uterus measures 10.5 x 7.2 x 4.2 cm. The fallopian tubes are symmetrical and measure 8 cm in length, 0.4 cm in diameter. Right ovary measures 3.1 x 1.9 x 1.2 cm. Left ovary measures 3.2 x 1.8 x 1.2 cm. Serosal surface is normal. The cervix measures 3.4 cm in length, 3.6 cm in diameter. Mucosa over the exocervix is unremarkable.

The bivalved uterus shows several nabothian-like cysts of the endocervical canal. Endometrium is distorted by papillary lesion involving total surface of the endometrium measuring 11 x 6 cm. Cross-sections of the tumor show tan-white fibrous structure with a maximum thickness of 2.1 cm that on posterior surface is 0.5 cm from the serosal surface. Cross-sections of the ovaries show normal structure. Representative sections submitted as follows:

- A1,A2 -cervix; anterior, posterior
A3 -cul-de-sac
A4,A5 -isthmus anterior, posterior
A6-A10 -anterior myometrium
A11-A15 -posterior myometrium of the area of the deepest invasion
A16-A18 -right adnexa, fallopian tube in toto
A19-A21 -left adnexa, fallopian tube in toto

This user-modifiable Microsoft Word document does not constitute a patient report.
It is provided as a tool for research purposes only.

Source: NCI Genomic Data Commons file d993e302-8c01-4d5f-b106-4211e37042e1 (TCGA-KP-A3W3.9D8F170A-A4B1-463A-B92C-357870762EAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).